Surgical pathology report (de-identified scan), TCGA case TCGA-29-1770, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1770-02A (Recurrent Tumor).

[REDACTED]

Surg Path

CLINICAL HISTORY:
Recurrent OV CA.

GROSS EXAMINATION:

A. "Pelvic mass", in formalin. Received is a 7.5 x 5.0 x 2.5 cm aggregate of tan-pink, soft, and hemorrhagic membranous tissue with attached adipose tissue. One portion of the specimen is studded with soft, tan-pink, papillary excrescences (A1) (A2-A5).

B. "Right gutter", in formalin. Received is a 1.0 x 0.8 x 0.5 cm fragment of fibroadipose tissue. The specimen is submitted entirely as block B1.

C. "Left gutter", in formalin. Received is a 0.7 x 0.4 x 0.3 cm pink-tan fragment of fibroadipose tissue. The specimen is submitted entirely as block C1.

D. "Bladder flap", in formalin. Received is a 0.9 x 0.7 x 0.2 cm tan tissue fragment. The specimen is submitted entirely as block D1.

E. "Omentum", in formalin. Received is a 6.5 x 4.0 x 1.0 cm fragment of adipose tissue. On cut section, the parenchyma is uniformly tan-yellow with no gross lesions (E1-E2).

F. "Appendices epiploica", in formalin. Received is a 4.3 x 2.5 x 0.5 cm elliptical portion of soft, pink-tan adipose tissue, covered by a thin membrane. On cut section, the parenchyma is uniform tan-yellow with no lesions (F1).

G. "Hernia sac", in formalin. Received is a 7.5 x 4.7 x 3.0 cm aggregate of soft to firm, tan-yellow fragments of adipose tissue covered by a wrinkled pink-tan membrane. One of the tissue fragments, 4.0 x 1.3 x 1.5 cm, is covered along one side with soft pink-tan papillary projections (G1). The remaining tissue has a uniform soft, tan-yellow parenchyma interspersed with minimal amounts of white fibrous tissue (G2).

[REDACTED]

DIAGNOSIS:

RECURRENT SEROUS ADENOCARCINOMA (FIGO GRADE II) INVOLVING:

A. PELVIC MASS.

THE FOLLOWING ARE FREE OF TUMOR:

B. RIGHT GUTTER.

C. LEFT GUTTER.

D. BLADDER FLAP.

E. OMENTUM.

F. APPENDIX EPIPLOICA.

G. HERNIA SAC.

ICB-0-3 Recurrence
adenocarcinoma, serous, NOS 8441/3
Site: pelvis, soft tissue C49.5

hw
2/27/15

NOTE: The recurrent tumor is consistent with the primary tumor originating in the ovary

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file a021bbfa-9838-439a-9b9b-cc9da59f5dd1 (TCGA-29-1770.49220236-FBFE-44AA-89BC-FC4E7CBC94FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).